MMRF case MMRF_1808 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ba52d897-736b-4ea7-a304-e8f6933ede90

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Dead; Days to death: 729 days (2.0 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.5 years (20,619 days); Days to last known disease status: 729 days (2.0 years); Days to last follow up: 729 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 65 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 15 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 33 days; Days to treatment end: 71 days.
   Treatment given: Therapeutic agents: Carfilzomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 79 days; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 174 days; Days to treatment end: 174 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 175 days; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 267 days; Days to treatment end: 396 days (1.1 years).
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 267 days; Days to treatment end: 367 days (1.0 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 367 days (1.0 years); Days to treatment end: 501 days (1.4 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Regimen or line of therapy: First line of therapy; Days to treatment start: 612 days (1.7 years); Days to treatment end: 612 days (1.7 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 729.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 0): M Protein 2.01 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.092 mg/dL; Immunoglobulin G 26.6 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.96 g/L; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 44.1 g/L; Total Protein 9.6 g/dL; Glucose 4.84 mmol/L.
- Day 97 (ECOG 0): M Protein 1.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.054 mg/dL; Immunoglobulin G 17.1 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 1.56 g/L; Lactate Dehydrogenase 3.9 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 18 ×10⁹/L; Absolute Neutrophil 14 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 7.9 g/dL; Glucose 5.78 mmol/L.
- Day 156 (ECOG 1): M Protein 0.94 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.511 mg/dL; Immunoglobulin G 15.7 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.97 g/L; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.03 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 5.83 mmol/L.
- Day 237 (ECOG 0): M Protein 0.79 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.851 mg/dL; Immunoglobulin G 14.8 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 1.72 µg/mL; Lactate Dehydrogenase 3.88 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 6.32 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 6.11 mmol/L.
- Day 329 (ECOG 0): M Protein 0.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.08 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 5.17 mmol/L.
- Day 442 (ECOG 0): M Protein 0.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.864 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 1.68 g/L; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 7.5 g/dL; Glucose 5.12 mmol/L.
- Day 519 (ECOG 0): M Protein 0.47 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 2.39 g/L; Lactate Dehydrogenase 3.95 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 7.2 g/dL; Glucose 6.93 mmol/L.
- Day 694: Hemoglobin 7.07 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L.

Other clinical attributes
- Day -13: Weight: 107 kg; Height: 170 cm.

Family history
- Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1808_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1808_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
